Somatic mutation profile of tumor specimen 0DH5XM from CCDI case PBBTYW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Synovial sarcoma, spindle cell; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 15.2 years (5,547 days).
Specimen 0DH5XM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cde30e7-2682-43ab-a510-ddba727f5186.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5UA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5a1ac81-6fd0-4bcc-a446-c73ec523bf4a

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2orf73 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 259/545 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs760698927; called by muse, mutect2, varscan2
- ZBTB8A | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 187/479 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100331466; called by muse, mutect2, varscan2
- DYNC1H1 | c.3056A>G p.Y1019C | Missense Mutation (SNP) | VAF 27/640 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- KIF1A | c.3745G>A p.E1249K (on ENST00000320389 / NM_001379639.1; = p.E1241K on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 369/741 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- OR8D4 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 252/501 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYC | c.627C>T p.A209= (on ENST00000377970; = p.A224= on NM_002467.6) | Silent (SNP) | VAF 204/400 reads (51%) | called by muse, mutect2, varscan2
- NAGPA | c.906C>T p.Y302= | Silent (SNP) | VAF 166/395 reads (42%) | called by muse, mutect2, varscan2
- OGFR | c.1971G>A p.A657= | Silent (SNP) | VAF 581/1312 reads (44%) | catalogued as rs146902893; called by muse, mutect2, varscan2
- RFX1 | c.513+59C>A | Intron (SNP) | VAF 27/156 reads (17%) | called by muse, mutect2, varscan2
